Somatic mutation profile of tumor specimen 0DTYB3 from CCDI case PBCJWL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Subependymal giant cell astrocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 6.7 years (2,455 days).
Specimen 0DTYB3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9213f399-d176-4c2d-a9ce-8eb2f9afabaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTYAT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00e2f651-e61f-4580-b8c2-d7801b54e8eb

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Nonsense Mutation 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 375/885 reads (42%) | catalogued as rs118203631, CM971520, CX024084, COSV53763295; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- PSMD12 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 88/446 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TCEAL1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 22/432 reads (5%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- UROD | c.214-23A>C | Intron (SNP) | VAF 58/415 reads (14%) | called by muse, mutect2, varscan2
